Somatic mutation profile of tumor specimen TCGA-VD-A8KO-01A (aliquot TCGA-VD-A8KO-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KO, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.6 years (18,844 days).
Specimen TCGA-VD-A8KO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56530ef5-8715-4905-922f-2ad59ec351a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KO-10A (Blood Derived Normal), aliquot TCGA-VD-A8KO-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/356ad3d7-de3f-4e4f-8924-d48df6dded69

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Del 1, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 43/98 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARAP1 | c.2790G>A p.R930= (on ENST00000393609 / NM_001040118.2; = p.R685= on NM_015242.4) | Splice Region (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- EIF1AX | c.20_22del p.K7_G8delinsR | In Frame Del (DEL) | VAF 35/36 reads (97%) | called by mutect2, pindel, varscan2
- OR2B3 | c.873C>A p.S291R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TET3 | c.2057_2058del p.P686Qfs*19 | Frame Shift Del (DEL) | VAF 28/63 reads (44%) | called by mutect2, pindel, varscan2
- TRAM1 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIST | n.9960C>T | RNA (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
